Surgical pathology report (de-identified scan), TCGA case TCGA-78-7542, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Prince Charles Hospital, specimen TCGA-78-7542-01A (Primary Tumor).

[REDACTED]

A: RIGHT UPPER LOBECTOMY

Macroscopy:

Specimen consists of lung measuring 100 x 100 x 40 mm containing a mass measuring 50 x 30 x 30 mm, causing puckering of the overlying visceral pleura. There is a staple line present measuring 55 mm in length and tumour extends to within 40 mm of this macroscopically. Serial sectioning of the remaining lung tissue reveals no other focal lesions. [Block A1 bronchial resection margin, A2 tumour and staple line, A3 tumour and pleura, A4-A5 nodes n

Microscopy:

Sections show poorly differentiated adenocarcinoma, some of which is forming sheets of cells with occasional multinucleated giant cells. In other areas the tumour is growing along the preexisting alveolar septa. There is no involvement of visceral pleura and the bronchial resection margins are free of tumour. The residual lung shows some changes of subpleural emphysema. Lymph nodes show foci of necrosis and reactive changes but no evidence of malignancy.

B: RML NODULE

Macroscopy:

Specimen consists of nodule covered by pleura on one surface, measuring 14 x 9 x 5mm.

Microscopy:

Sections show a lymph node in which there are reactive changes but no evidence of malignancy.

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 42f5945f-750c-4d86-ab01-8ce039ca0b03 (TCGA-78-7542.07A2FAC9-0532-442E-AE75-5A7CC5D298D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).